Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA58, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA58-01A (Primary Tumor).

Specimen Comments

SPECIMEN

- 1 - Bladder, uterus, tubes, ovaries, cervix.
- 2 - Left external iliac.
- 3 - Left obturator.
- 4 - Right obturator.
- 5 - Right ureteric resection margin.

CLINICAL DETAILS

Muscle invasive bladder cancer. Cystectomy. Specimen is bladder, ovaries, uterus. Palpable right obturator nodes ? mets.

MACROSCOPY

- 1 - Specimen comprises bladder, uterus, both tubes and ovaries. Bladder measures 95 mm supero-inferiorly x 65 mm medio-lateral and 30 mm anterior-posterior. On opening, the bladder shows a grey/white ulcerated tumour on posterior and right lateral walls measuring 25 mm x 20 mm x 10 mm. The tumour is seen infiltrating into the muscle.
Uterus 60 mm supero-inferiorly x 35 mm medio-lateral and 50 mm anterior-posterior. On slicing, it is unremarkable. Right tube 35 x 4 mm, right ovary 20 x 8 mm. Left tube 45 x 3 mm, left ovary 18 x 10 mm.
- 2 - Fatty piece of tissue measuring 40 x 22 x 10 mm, containing two lymph nodes, the larger measures 15 mm.
- 3 - Fatty piece of tissue measuring 40 x 20 x 10 mm. Slicing shows multiple nodes, the largest 15 mm diameter.
- 4 - Fatty piece of tissue measuring 70 x 35 x 20 mm. Multiple lymph nodes identified, the largest is probably an involved node measuring 25 mm.
- 5 - Tubular piece of tissue measuring 7 x 6 mm.

MICROSCOPY

- 1 - This bladder shows a Grade 3, poorly differentiated transitional cell carcinoma. The tumour is solid with no papillary areas and is composed of pleomorphic cells. It infiltrates into the muscularis propria and focally through it into the fat (pT3a). The background epithelium shows squamous metaplasia, but no dysplasia or carcinoma-in-situ is identified. There is no vascular invasion. The urethral and right ureteric resection margins do not show any evidence of malignancy. The cervix is unremarkable. The endometrium shows cystic atrophy. The myometrium, both tubes and ovaries are unremarkable. No evidence of metastatic tumour is identified.
- 2 - One out of two lymph nodes shows metastatic transitional cell carcinoma.
- 3 - Three lymph nodes without metastatic deposits identified.
- 4 - One out of six lymph nodes shows metastatic transitional cell carcinoma.
- 5 - The right ureteric margin does not show any evidence of malignancy.

SUMMARY

Cystectomy - transitional cell carcinoma G3 pT3a, N2.

Ref:

Pathologists -

ICD O-3
Carcinoma, urothelial NOS 8120/3
Carcinoma, transitional cell NOS 8120/3
Site Bladder wall C67.9
Jr 4/30/14

Pw TSS,
O2, squamous

Source: NCI Genomic Data Commons file fd4eeb80-7324-411c-b9fa-0bba2a8a49f6 (TCGA-ZF-AA58.31EED29A-65A9-4DB1-8E78-799A927D59F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).